Somatic mutation profile of tumor specimen TCGA-B8-5164-01A (aliquot TCGA-B8-5164-01A-01D-1421-08) from TCGA case TCGA-B8-5164, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Tumor grade: G3; Age at diagnosis: 65.3 years (23,863 days).
Specimen TCGA-B8-5164-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0be0ebd8-9f58-45c8-8d0f-24895a9fed3a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B8-5164-10A (Blood Derived Normal), aliquot TCGA-B8-5164-10A-01D-1421-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b85fd58d-7e0d-444e-b4ca-9130be0b3e85

The open-access MAF lists 91 somatic variants for this specimen: 72 protein-altering or splice-affecting, 18 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 52, Silent 18, Frame Shift Del 9, Nonsense Mutation 5, In Frame Del 2, Frame Shift Ins 2, Splice Site 2, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCB1 | c.1784C>G p.A595G | Missense Mutation (SNP) | VAF 40/201 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV55947195; called by muse, mutect2, varscan2
- ABCG1 | c.1627A>C p.M543L | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV59201863; called by muse, mutect2
- ADAM30 | c.1681A>C p.N561H | Missense Mutation (SNP) | VAF 61/318 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV65560601; called by muse, mutect2, varscan2
- AFAP1L1 | c.491G>T p.S164I | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.347); catalogued as rs1460472192, COSV57044351; called by muse, mutect2
- ANKS3 | c.54G>T p.L18F | Missense Mutation (SNP) | VAF 23/113 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs781136512, COSV58507929; called by muse, mutect2, varscan2
- ARHGAP28 | c.907A>C p.N303H (on ENST00000383472 / NM_001366230.1; = p.N144H on NM_001010000.3) | Missense Mutation (SNP) | VAF 51/243 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.125); catalogued as COSV51633768; called by muse, mutect2, varscan2
- ARHGEF28 | c.3899G>A p.C1300Y | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.15); PolyPhen benign (0.015); catalogued as COSV55250337; called by muse, mutect2
- BICD1 | c.2335T>G p.L779V | Missense Mutation (SNP) | VAF 5/129 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55676361; called by muse, mutect2
- BRDT | c.2530G>T p.E844* | Nonsense Mutation (SNP) | VAF 42/211 reads (20%) | catalogued as COSV62863840; called by muse, mutect2, varscan2
- C5orf22 | c.444C>G p.N148K | Missense Mutation (SNP) | VAF 43/272 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.76); catalogued as rs763836626, COSV57597851; called by muse, mutect2, varscan2
- CAPRIN2 | c.2432C>G p.S811C | Missense Mutation (SNP) | VAF 14/258 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.891); catalogued as rs1290326361, COSV51831375; called by muse, mutect2
- CCDC40 | c.205G>C p.V69L | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.006); catalogued as COSV53897969; called by muse, mutect2, varscan2
- CELSR2 | c.3100G>A p.V1034I | Missense Mutation (SNP) | VAF 36/165 reads (22%) | SIFT tolerated (0.16); PolyPhen benign (0.078); catalogued as COSV54768535; called by muse, mutect2, varscan2
- CHD2 | c.4188del p.N1397Tfs*9 | Frame Shift Del (DEL) | VAF 49/204 reads (24%) | catalogued as COSV67707380; called by mutect2, pindel*, varscan2*
- CHID1 | c.1162T>A p.Y388N | Missense Mutation (SNP) | VAF 15/112 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60258192; called by muse, mutect2, varscan2
- CLASRP | c.643C>A p.Q215K | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT tolerated (0.4); catalogued as COSV55515035; called by muse, mutect2, varscan2
- CPEB4 | c.141_143del p.N48del | In Frame Del (DEL) | VAF 35/236 reads (15%) | catalogued as rs772383887; called by pindel, varscan2
- CYP1A2 | c.289G>A p.A97T | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs545726003, COSV59659266; called by muse, mutect2, varscan2
- CYP4F12 | c.95C>T p.A32V | Missense Mutation (SNP) | VAF 39/191 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.073); catalogued as COSV61172857; called by muse, mutect2, varscan2
- DAPK2 | c.742G>T p.E248* | Nonsense Mutation (SNP) | VAF 45/226 reads (20%) | catalogued as COSV56044268; called by muse, mutect2, varscan2
- DDX58 | c.1745T>A p.I582N | Missense Mutation (SNP) | VAF 36/187 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.157); catalogued as COSV65882601; called by muse, mutect2, varscan2
- DHX35 | c.745T>A p.Y249N | Missense Mutation (SNP) | VAF 85/440 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.742); catalogued as COSV52668495; called by muse, mutect2, varscan2
- DHX35 | c.746A>T p.Y249F | Missense Mutation (SNP) | VAF 87/432 reads (20%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.767); catalogued as COSV52668529; called by muse, mutect2, varscan2
- DNAH11 | c.11485A>C p.S3829R | Missense Mutation (SNP) | VAF 38/240 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV60945424; called by muse, mutect2, varscan2
- DNAH2 | c.2101A>T p.I701F | Missense Mutation (SNP) | VAF 74/292 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV66717627; called by muse, mutect2, varscan2
- DRD5 | c.1306C>A p.R436S | Missense Mutation (SNP) | VAF 22/129 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.149); catalogued as COSV58576967, COSV58577162; called by muse, mutect2, varscan2
- EPN2 | c.53C>T p.S18L | Missense Mutation (SNP) | VAF 21/99 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV59060388; called by muse, mutect2, varscan2
- FLNB | c.270G>C p.E90D | Missense Mutation (SNP) | VAF 36/139 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.017); catalogued as COSV55873500; called by muse, mutect2, varscan2
- HELLS | c.1580A>C p.E527A | Missense Mutation (SNP) | VAF 42/201 reads (21%) | SIFT tolerated (0.35); PolyPhen benign (0.197); catalogued as COSV53295259; called by muse, mutect2, varscan2
- ITGAD | c.3135T>G p.N1045K | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.191); catalogued as COSV54931649; called by muse, mutect2, varscan2
- KHK | c.113A>G p.Q38R | Missense Mutation (SNP) | VAF 11/150 reads (7%) | SIFT deleterious (0.05); PolyPhen benign (0.041); catalogued as COSV53153829; called by muse, mutect2
- KIF2A | c.196C>A p.L66I | Missense Mutation (SNP) | VAF 32/182 reads (18%) | SIFT tolerated (0.05); PolyPhen benign (0.012); catalogued as COSV66944851; called by muse, mutect2, varscan2
- KLK5 | c.118A>C p.N40H | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0.133); catalogued as COSV60449829; called by muse, mutect2, varscan2
- LIMA1 | c.1395G>A p.W465* | Nonsense Mutation (SNP) | VAF 68/348 reads (20%) | catalogued as COSV57964485; called by muse, mutect2, varscan2
- LINGO2 | c.1106G>A p.R369Q | Missense Mutation (SNP) | VAF 19/74 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as rs746922513, COSV58057110; called by muse, mutect2, varscan2
- MARF1 | c.2873C>G p.S958C | Missense Mutation (SNP) | VAF 28/141 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60020883; called by muse, mutect2, varscan2
- MYLK | c.1318A>C p.I440L | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated (0.76); PolyPhen benign (0.013); catalogued as COSV60606589; called by muse, mutect2, varscan2
- NDUFA10 | c.268G>T p.G90W | Missense Mutation (SNP) | VAF 18/94 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as COSV53153125; called by muse, mutect2
- NLRP4 | c.1607A>G p.K536R | Missense Mutation (SNP) | VAF 28/155 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.127); catalogued as COSV56710466; called by muse, mutect2, varscan2
- NSMAF | c.1126-2A>G p.X376_splice | Splice Site (SNP) | VAF 12/55 reads (22%) | catalogued as COSV50684868; called by muse, mutect2, varscan2
- NUTM1 | c.1429G>T p.E477* | Nonsense Mutation (SNP) | VAF 21/139 reads (15%) | catalogued as COSV59216084; called by muse, mutect2, varscan2
- PCDH1 | c.2721G>C p.K907N | Missense Mutation (SNP) | VAF 43/192 reads (22%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.917); catalogued as COSV54612060; called by muse, mutect2, varscan2
- PCDH7 | c.2540C>T p.P847L | Missense Mutation (SNP) | VAF 32/179 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs374867601; called by muse, mutect2, varscan2
- PJA1 | c.757G>C p.E253Q | Missense Mutation (SNP) | VAF 27/72 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.878); catalogued as COSV64052796; called by muse, mutect2, varscan2
- POM121 | c.3082C>G p.P1028A (on ENST00000434423; = p.P763A on NM_172020.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/109 reads (15%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.942); catalogued as COSV57513041; called by muse, mutect2, varscan2
- PRKCQ | c.1342T>G p.F448V | Missense Mutation (SNP) | VAF 19/106 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54108416; called by muse, mutect2, varscan2
- PTPRS | c.1063G>T p.G355C | Missense Mutation (SNP) | VAF 12/102 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53613646; called by muse, mutect2, varscan2
- RAC2 | c.35+1G>A p.X12_splice | Splice Site (SNP) | VAF 6/47 reads (13%) | catalogued as COSV99969661; called by muse, mutect2, varscan2
- RND1 | c.13C>G p.R5G | Missense Mutation (SNP) | VAF 13/83 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.931); catalogued as COSV59044974; called by muse, mutect2, varscan2
- SIRT7 | c.14G>A p.G5D | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT tolerated (0.36); PolyPhen benign (0.039); catalogued as COSV60815123; called by muse, mutect2, varscan2
- SLC26A5 | c.1088A>C p.N363T | Missense Mutation (SNP) | VAF 45/255 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.065); catalogued as COSV59699394; called by muse, mutect2, varscan2
- SLC39A6 | c.1756G>A p.E586K | Missense Mutation (SNP) | VAF 20/102 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.636); catalogued as COSV52367873, COSV52368312; called by muse, mutect2, varscan2
- SNX17 | c.1129C>G p.Q377E | Missense Mutation (SNP) | VAF 48/262 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.837); catalogued as COSV52006973; called by muse, mutect2, varscan2
- UXT | c.97C>T p.R33* | Nonsense Mutation (SNP) | VAF 3/21 reads (14%) | catalogued as COSV60039268; called by muse, mutect2
- VWF | c.625T>A p.S209T | Missense Mutation (SNP) | VAF 48/230 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as COSV54614538; called by muse, mutect2, varscan2
- WDR92 | c.119C>G p.A40G | Missense Mutation (SNP) | VAF 25/95 reads (26%) | SIFT deleterious (0.05); PolyPhen benign (0.079); catalogued as COSV54560824; called by muse, mutect2, varscan2
- XRCC5 | c.1141A>C p.I381L | Missense Mutation (SNP) | VAF 52/305 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.458); catalogued as COSV67535248; called by muse, mutect2, varscan2
- XRN1 | c.2671A>T p.I891F | Missense Mutation (SNP) | VAF 28/139 reads (20%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.535); catalogued as COSV53809223; called by muse, mutect2, varscan2
- ZFYVE9 | c.164G>C p.S55T | Missense Mutation (SNP) | VAF 34/182 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.039); catalogued as rs961411603, COSV55091600; called by muse, mutect2, varscan2
- ZNFX1 | c.450A>C p.E150D | Missense Mutation (SNP) | VAF 61/290 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.836); catalogued as COSV65574335; called by muse, mutect2, varscan2
- ADRB2 | c.810del p.A271Pfs*5 | Frame Shift Del (DEL) | VAF 21/130 reads (16%) | called by mutect2, pindel, varscan2
- ARID1B | c.1985dup p.S663Ifs*11 | Frame Shift Ins (INS) | VAF 29/184 reads (16%) | called by mutect2, pindel, varscan2
- ATP4A | c.2040_2044del p.L681Gfs*50 | Frame Shift Del (DEL) | VAF 15/111 reads (14%) | called by mutect2, pindel, varscan2
- CST11 | c.302dup p.N101Kfs*26 | Frame Shift Ins (INS) | VAF 44/215 reads (20%) | called by mutect2, pindel, varscan2
- CTSE | c.346del p.T116Rfs*48 (on ENST00000360218; = p.T116Rfs*43 on NM_001910.4) | Frame Shift Del (DEL) | VAF 14/91 reads (15%) | called by mutect2, pindel, varscan2
- DOCK8 | c.3795del p.N1266Ifs*5 | Frame Shift Del (DEL) | VAF 71/380 reads (19%) | called by mutect2, pindel, varscan2
- GABPB1 | c.142_163del p.Y48Rfs*8 | Frame Shift Del (DEL) | VAF 21/195 reads (11%) | called by mutect2, pindel
- NOL11 | c.783_786del p.N261Kfs*15 | Frame Shift Del (DEL) | VAF 11/89 reads (12%) | called by pindel, varscan2
- RLF | c.3083_3084del p.D1028Afs*6 | Frame Shift Del (DEL) | VAF 25/129 reads (19%) | called by mutect2, pindel, varscan2
- SPTBN5 | c.341del p.F114Sfs*84 | Frame Shift Del (DEL) | VAF 8/76 reads (11%) | called by mutect2, varscan2
- TXLNB | c.699_701del p.Q234del | In Frame Del (DEL) | VAF 20/125 reads (16%) | called by mutect2, pindel, varscan2
- WDR90 | c.4186G>T p.V1396L | Missense Mutation (SNP) | VAF 5/87 reads (6%) | SIFT deleterious (0.05); PolyPhen benign (0.066); called by muse, mutect2
- ADAM17 | c.1368A>G p.Q456= | Silent (SNP) | VAF 9/217 reads (4%) | catalogued as COSV60397988; called by muse, mutect2
- ALDOB | c.177C>T p.F59= | Silent (SNP) | VAF 55/278 reads (20%) | catalogued as rs1164829727, COSV66397490; called by muse, mutect2, varscan2
- ATP2A3 | c.736C>A p.R246= | Silent (SNP) | VAF 12/65 reads (18%) | catalogued as COSV59227061, COSV59227232; called by muse, mutect2, varscan2
- CDKAL1 | c.564G>C p.R188= | Silent (SNP) | VAF 31/179 reads (17%) | catalogued as COSV51179455, COSV51180990; called by muse, mutect2, varscan2
- CHDH | c.1275G>T p.G425= | Silent (SNP) | VAF 15/82 reads (18%) | catalogued as COSV59456393; called by muse, mutect2, varscan2
- CSF3R | c.1962G>A p.R654= | Silent (SNP) | VAF 45/281 reads (16%) | catalogued as COSV58964557; called by muse, mutect2, varscan2
- EDRF1 | c.1950A>T p.L650= (on ENST00000356792 / NM_001202438.2; = p.L616= on NM_015608.2) | Silent (SNP) | VAF 22/146 reads (15%) | catalogued as COSV61762807; called by muse, mutect2, varscan2
- FGD5 | c.3930G>C p.L1310= | Silent (SNP) | VAF 4/23 reads (17%) | catalogued as COSV53239209; called by muse, mutect2
- FIZ1 | c.675G>A p.V225= | Silent (SNP) | VAF 4/13 reads (31%) | catalogued as COSV55607335; called by muse, mutect2, varscan2
- KRT2 | c.87G>T p.V29= | Silent (SNP) | VAF 6/26 reads (23%) | catalogued as COSV59009556; called by muse, mutect2
- MED15 | c.979T>C p.L327= | Silent (SNP) | VAF 37/190 reads (19%) | catalogued as COSV53027790; called by muse, mutect2, varscan2
- MMP28 | c.1527C>T p.G509= | Silent (SNP) | VAF 8/39 reads (21%) | called by muse, mutect2, varscan2
- NFATC1 | c.2313T>G p.L771= | Silent (SNP) | VAF 18/109 reads (17%) | called by muse, mutect2
- OPN1SW | c.858C>A p.T286= | Silent (SNP) | VAF 7/50 reads (14%) | catalogued as COSV50821368; called by muse, mutect2, varscan2
- PRSS54 | c.726C>T p.N242= | Silent (SNP) | VAF 12/65 reads (18%) | catalogued as rs368704231; called by muse, mutect2, varscan2
- RB1CC1 | c.4323C>T p.S1441= | Silent (SNP) | VAF 61/234 reads (26%) | catalogued as COSV50244212; called by muse, mutect2, varscan2
- SLC2A8 | c.1194A>G p.S398= | Silent (SNP) | VAF 14/75 reads (19%) | catalogued as COSV64894241; called by muse, mutect2, varscan2
- STON1 | c.1662G>A p.Q554= | Silent (SNP) | VAF 44/240 reads (18%) | catalogued as rs1461474242, COSV59127764; called by muse, mutect2, varscan2
- ARHGEF25 | chr12:57610657 G>T | 5'Flank (SNP) | VAF 6/51 reads (12%) | catalogued as COSV54085226; called by muse, mutect2, varscan2
